Gene-level copy-number profile of tumor specimen TCGA-29-2429-01A from TCGA case TCGA-29-2429, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 79.8 years (29,156 days).
Specimen TCGA-29-2429-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.bfd6404a-1c99-45ca-b16b-4cf449308043.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-29-2429-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/00e90001-67a3-4351-b981-4f747ff2fd43

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 6,227; copy number 3: 1,695; copy number 4: 28,958; copy number 5: 3,608; copy number 6: 12,360; copy number 7: 1,757; copy number 8: 3,105; copy number 9: 562; copy number 10: 284; copy number 11: 369; copy number 12: 203; copy number 13: 166; copy number 14: 82; copy number 15: 166; copy number 16: 34; copy number 18: 59; copy number 19: 156; copy number 24: 10; copy number 26: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-29-2429-01A-01D-1043-01): tumor purity 0.58, ploidy 2.38, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,102 genes in 33 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–2,405,442, 153 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr1:155,002,630–156,456,763, 89 genes, copy number 9–15 (broad region; genes not listed).
- chr1:183,138,402–183,472,265, 7 genes, copy number 15: LAMC1-AS1, LAMC2, NMNAT2, AL354953.1, RPS3AP8, AL449223.1, SMG7-AS1.
- chr2:27,212,027–28,870,309, 54 genes, copy number 11–14 (within-gene range 6–14): ATRAID, CAD, SLC30A3, DNAJC5G, TRIM54, UCN, MPV17, GTF3C2, GTF3C2-AS1, AC074117.1, EIF2B4, SNX17, ZNF513, PPM1G, FTH1P3, NRBP1, KRTCAP3, IFT172, AC074117.2, RNU6-986P, FNDC4, GCKR, C2orf16, ZNF512, AC074091.2, CCDC121, GPN1, AC074091.1, SUPT7L, SLC4A1AP, LINC01460, MRPL33, RBKS, BABAM2, MYG1P1, MIR4263, FAM133EP, AC096552.1, AC093690.1, RPL23AP34, FLJ31356, FOSL2, AC104695.3, AC104695.2, AC104695.1, PLB1, SNRPGP7, AC074011.1, RNA5SP89, AC092164.1, PPP1CB, SPDYA, AC097724.1, TRMT61B.
- chr2:112,973,203–114,007,304, 44 genes, copy number 15–24: IL36G, HMGN2P23, POLR2DP1, IL36A, IL36B, IL36RN, IL1F10, RNU6-1180P, IL1RN, PSD4, AC016683.1, PAX8-AS1, PAX8, AC016745.1, IGKV1OR2-108, AC016745.2, CBWD2, FOXD4L1, LINC01961, PGM5P4-AS1, PGM5P4, FAM138B, AL078621.2, MIR1302-3, WASH2P, DDX11L2, AL078621.1, RPL23AP7, RABL2A, SNRPA1P1, ACRP1, AC017074.2, AC017074.1, RNU6-744P, SLC35F5, MIR4782, AC104653.2, AC104653.1, AC110769.2, ACTR3, AC110769.3, LINC01191, AC110769.1, U3.
- chr2:132,037,787–135,047,468, 45 genes, copy number 10–12 (within-gene range 8–12): AC093787.1, AC098826.3, AC098826.1, AC098826.2, ANKRD30BL, RNU6-1132P, RNA5-8SP5, MIR663B, CDC27P1, AC097532.1, ZNF806, AC097532.2, AC097532.3, FAM201B, RNU6-175P, GPR39, YBX1P7, RN7SKP103, LYPD1, AC010974.1, NCKAP5, AC010974.2, AC016909.1, NCKAP5-AS1, AC011755.1, NCKAP5-AS2, RNU6-579P, RN7SKP154, NCKAP5-IT1, AC011243.1, RN7SKP93, AC092623.1, MGAT5, MIR3679, RNA5SP104, EDDM3CP, TMEM163, AC110620.2, CCNT2-AS1, VDAC2P4, AC110620.1, ACMSD, MIR5590, CCNT2, MAP3K19.
- chr2:148,595,158–150,635,818, 27 genes, copy number 10: RPS29P8, EPC2, RNU2-9P, UBBP3, KIF5C-AS1, RPS20P13, USP8P2, KIF5C, AC105402.1, LYPD6B, TXNP5, AC009230.1, FAM8A3P, LYPD6, RPL17P13, MMADHC, MMADHC-DT, RNU6-601P, LINC01931, AC016682.1, LINC01818, LINC01817, RND3, LINC01920, AC104777.2, AC104777.1, LINC02612.
- chr2:169,827,454–171,999,859, 33 genes, copy number 9–11 (within-gene range 8–11): UBR3, NSA2P5, RNU6-1006P, MYO3B, MYO3B-AS1, HMGB1P4, AC007277.1, AC007277.2, AC007405.1, LINC01124, SP5, EIF2S2P4, AC007405.3, Y_RNA, ERICH2, GAD1, AC007405.2, AC007405.4, AC010092.1, GORASP2, TLK1, METTL8, RPS26P20, DCAF17, DAP3P2, AC007969.1, RPS15P4, CYBRD1, RPL21P38, DYNC1I2, SLC25A12, RNU6-182P, HAT1.
- chr2:175,022,214–178,108,339, 75 genes, copy number 12 (within-gene range 8–12) (broad region; genes not listed).
- chr2:186,032,884–187,003,377, 12 genes, copy number 13: LINC01473, AC104058.1, RPL23AP35, AC017071.1, MED28P3, ZC3H15, DPRXP1, ITGAV, AC017101.1, FAM171B, ZSWIM2, IMPDH1P7.
- chr3:112,133,423–112,846,856, 17 genes, copy number 11–13: TBILA, SLC9C1, AC128688.1, AC112487.1, AC112487.2, CD200, AC092894.1, BTLA, OR7E100P, AC092692.1, ATG3, SLC35A5, CCDC80, AC048334.1, LINC02042, CD200R1L-AS1, CD200R1L.
- chr3:167,864,773–170,181,749, 46 genes, copy number 12–16 (within-gene range 6–16): LRRC77P, AC026353.1, MEMO1P3, AC128713.1, HMGN2P26, GOLIM4, AC069243.1, EGFEM1P, AC124893.1, RNU2-20P, MIR551B, RPSAP33, RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997, MECOM, MECOM-AS1, RPL22P1, AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1, GPR160, RNU4-38P, KMT5AP3, PHC3, RNU6-315P.
- chr6:17,393,505–19,894,214, 34 genes, copy number 14 (within-gene range 8–14): CAP2, RPL7P26, SUMO2P13, AL138824.1, FAM8A1, NUP153, RNU6-190P, AL138724.1, RNA5SP204, Y_RNA, KIF13A, AL023807.1, NHLRC1, TPMT, KDM1B, DEK, Y_RNA, AL138825.1, RNU6-263P, DDX18P3, IMPDH1P9, RNF144B, MIR548A1HG, MIR548A1, AL589647.1, AL357052.1, LNC-LBCS, RPL5P20, RNA5SP205, KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL022726.1.
- chr6:30,688,047–32,820,466, 191 genes, copy number 11 (broad region; genes not listed).
- chr6:161,347,417–162,727,775, 1 gene, copy number 10 (within-gene range 6–10): PRKN.
- chr6:162,568,379–162,569,728, 1 gene, copy number 10: KRT8P44.
- chr7:46,477,822–48,927,454, 28 genes, copy number 9: AC004869.1, HMGN1P19, AC011294.1, EPS15P1, AC004870.4, AC004870.2, AC004870.3, MRPL42P4, AC004870.1, AC087175.1, TNS3, LINC01447, C7orf65, PKD1L1, LINC00525, C7orf69, AC069282.1, HUS1, SUN3, C7orf57, UPP1, ABCA13, AC091770.1, LINC02838, AC004899.1, AC004899.2, GDI2P1, CDC14C.
- chr7:54,330,670–57,655,392, 142 genes, copy number 10 (broad region; genes not listed).
- chr7:73,667,831–74,890,610, 32 genes, copy number 14: VPS37D, DNAJC30, BUD23, STX1A, MIR4284, RN7SL265P, ABHD11-AS1, ABHD11, CLDN3, CLDN4, METTL27, TMEM270, AC099398.1, ELN, ELN-AS1, LIMK1, EIF4H, MIR590, LAT2, RFC2, AC005081.1, CLIP2, GTF2IRD1, RNA5SP233, AC211433.2, AC211433.3, GTF2I, AC211433.1, PHBP15, NCF1, GTF2IRD2, STAG3L2.
- chr9:135,447,446–136,549,893, 43 genes, copy number 9: SOCS5P2, PPP1R26-AS1, PPP1R26, C9orf116, MRPS2, AL161452.1, LCN1, OBP2A, PAEP, LINC01502, PAEPP1, AL354761.1, GLT6D1, LCN9, SOHLH1, KCNT1, CAMSAP1, AL355574.1, UBAC1, NACC2, LINC02846, TMEM250, AL138781.1, LHX3, QSOX2, CCDC187, CR392000.1, CR392000.2, DKFZP434A062, GPSM1, DNLZ, CARD9, SNAPC4, ENTR1, PMPCA, INPP5E, SEC16A, C9orf163, NOTCH1, MIR4673, AL592301.1, MIR4674, NALT1.
- chr11:118,077,012–120,028,341, 102 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr14:68,605,396–68,862,525, 9 genes, copy number 10: AL121820.3, AL121820.2, AL121820.1, RPL12P7, AL133313.1, AL132986.1, RNU6-921P, ZFP36L1, MAGOH3P.
- chr14:76,013,679–77,761,207, 59 genes, copy number 12–26 (within-gene range 4–26): AC008015.1, AC016526.4, GPATCH2L, AC016526.2, AC016526.3, AC016526.1, ESRRB, AC008050.1, CYCSP1, RPSAP3, AC007376.1, AC007376.2, VASH1, AF111169.3, AF111169.1, VASH1-AS1, ANGEL1, AF111169.4, LRRC74A, RPL22P2, RN7SKP17, AF111169.2, AC007686.4, LINC01629, RN7SL356P, AC007686.1, IRF2BPL, AC007686.3, LINC02288, AC007686.2, LINC02289, AC007686.5, CIPC, AC007375.2, TMEM63C, ZDHHC22, AC007375.3, FAM204DP, AC007375.1, NGB, MIR1260A, POMT2, GSTZ1, TMED8, AC007954.1, SAMD15, NOXRED1, VIPAS39, AHSA1, AF111168.1, ISM2, SPTLC2, RN7SL587P, COX6CP11, ALKBH1, RPL21P10, ZMYND19P1, SLIRP, SNW1.
- chr17:50,719,565–50,756,219, 1 gene, copy number 11 (within-gene range 6–11): LUC7L3.
- chr17:50,761,029–51,336,240, 24 genes, copy number 11: ANKRD40CL, MIR8059, AC005921.4, AC005921.1, WFIKKN2, AC091062.1, RPL5P33, TOB1, TOB1-AS1, AC005920.4, AC005920.1, AC005920.3, SPAG9, AC005920.2, NME1, NME1-NME2, NME2, MBTD1, AC005839.1, AC006141.1, UTP18, LINC02071, AC005823.2, AC005823.1.
- chr19:12,965,159–19,113,030, 318 genes, copy number 9–19 (within-gene range 4–19) (broad region; genes not listed).
- chr19:27,638,483–33,557,470, 129 genes, copy number 10–19 (broad region; genes not listed).
- chr19:37,217,926–38,636,955, 59 genes, copy number 18: ZNF383, AC016590.1, LINC01535, AC016590.4, ZNF875, AC016590.3, AC016590.2, ZNF527, AC008806.1, ZNF569, ZNF570, ZNF793-AS1, AC022148.2, ZNF793, AC022148.1, ZNF571-AS1, ZNF540, ZNF571, ZFP30, ZNF781, AC093227.2, SELENOKP1, ZNF607, AC093227.1, AC093227.3, ZNF573, AC016582.2, AC016582.3, AC016582.1, WDR87, SIPA1L3, AC008395.1, AC011465.1, AC011479.3, AC011479.2, RN7SL663P, DPF1, SPINT2, PPP1R14A, AC011479.1, AC011479.4, Y_RNA, YIF1B, C19orf33, KCNK6, CATSPERG, AC005625.1, PSMD8, GGN, AC005789.1, SPRED3, FAM98C, RASGRP4, RYR1, AC067969.2, AC067969.1, MAP4K1, AC008649.1, EIF3K.
- chr20:472,498–1,393,164, 25 genes, copy number 10 (within-gene range 6–10): CSNK2A1, TCF15, SRXN1, AL121758.1, SCRT2, SLC52A3, FAM110A, RPS10P5, ANGPT4, RSPO4, AL110114.1, PSMF1, ACTG1P3, TMEM74B, AL031665.1, C20orf202, RAD21L1, SNPH, SDCBP2, AL136531.2, AL136531.3, SDCBP2-AS1, AL136531.1, FKBP1A, MIR6869.
- chr20:9,537,370–21,755,350, 200 genes, copy number 12–13 (broad region; genes not listed).
- chr20:57,105,741–57,712,780, 24 genes, copy number 11: AL157414.2, AL157414.1, AL157414.4, AL157414.3, BMP7, BMP7-AS1, AL122058.1, Y_RNA, MIR4325, RPL39P39, SPO11, RAE1, MTND1P9, MTRNR2L3, RBM38-AS1, RBM38, AL109955.1, HMGB1P1, CTCFL, PCK1, AL035541.1, ZBP1, PMEPA1, NKILA.
- chr20:63,218,041–64,313,132, 71 genes, copy number 11 (broad region; genes not listed).
- chr21:27,954,922–28,743,291, 7 genes, copy number 9: AJ006995.1, LINC00314, LINC01697, LINC01695, AF165147.1, LINC00161, U6.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
